Somatic mutation profile of tumor specimen 0DKRCZ from CCDI case PBBYBJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,827 days).
Specimen 0DKRCZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fc32fc6-ce05-4add-b16a-5030b1b7710d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRCA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0f08545-6311-47c2-b028-a1cc696e57dd

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 161/843 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as CM015872, CM081609; called by muse, mutect2, varscan2
- KAT14 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 45/1087 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100890043; called by muse, mutect2
- NUP62 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 137/639 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs1057193121; called by muse, mutect2, varscan2
- RIBC2 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 184/839 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs569608093; called by muse, mutect2, varscan2
- MFSD6L | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 183/736 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C7 | c.2385G>A p.S795= | Silent (SNP) | VAF 337/1800 reads (19%) | catalogued as rs751682564, COSV57473715; called by muse, mutect2, varscan2
- ACAT1 | c.-10C>G | 5'UTR (SNP) | VAF 44/313 reads (14%) | catalogued as rs373627341; called by muse, mutect2, varscan2
